Somatic mutation profile of tumor specimen TCGA-B0-5075-01A (aliquot TCGA-B0-5075-01A-01D-1462-08) from TCGA case TCGA-B0-5075, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 77.2 years (28,205 days).
Specimen TCGA-B0-5075-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e17379de-3fb3-4c84-b264-af7a93254ba1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5075-11A (Solid Tissue Normal), aliquot TCGA-B0-5075-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c0ef115-e2d8-4252-b96d-66f8d14e5abb

The open-access MAF lists 103 somatic variants for this specimen: 79 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 20, Frame Shift Del 9, Nonsense Mutation 5, In Frame Del 3, RNA 2, Splice Site 1, Frame Shift Ins 1, Splice Region 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HPRT1 | c.222C>A p.F74L | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs137852481, CM890066, CM952438, COSV53777024; ClinVar: pathogenic / other; called by muse, mutect2, varscan2
- AASDHPPT | c.597A>T p.E199D | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as COSV53790546; called by muse, varscan2
- ABCA7 | c.997C>G p.P333A | Missense Mutation (SNP) | VAF 76/334 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as COSV54037467; called by muse, mutect2, varscan2
- ABCA8 | c.3724G>T p.A1242S | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52212480; called by muse, mutect2, varscan2
- ABCC10 | c.1460C>T p.A487V (on ENST00000372530 / NM_001198934.2; = p.A444V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/262 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.265); catalogued as COSV55094043; called by muse, mutect2, varscan2
- AKNA | c.3683C>A p.S1228Y | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV56340386; called by muse, mutect2, varscan2
- ANGPTL3 | c.170T>A p.L57H | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52021481; called by muse, mutect2, varscan2
- ANKS1B | c.1640A>G p.Y547C | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.339); catalogued as rs560515400, COSV61376515; called by muse, mutect2, varscan2
- ATXN2L | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.973); catalogued as COSV57378929; called by muse, mutect2, varscan2
- BAHD1 | c.2319del p.R774Afs*25 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | catalogued as COSV60379277; called by mutect2, pindel
- CAND1 | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 92/394 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV73338578; called by muse, mutect2, varscan2
- CCDC33 | c.1429G>A p.G477S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs774231314, COSV51498416; called by muse, mutect2
- CDH2 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 59/221 reads (27%) | catalogued as COSV52296576; called by muse, mutect2, varscan2
- CEACAM5 | c.994T>G p.S332A | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.139); catalogued as COSV55755239; called by muse, mutect2, varscan2
- COL16A1 | c.2275G>A p.G759S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54714048; called by muse, mutect2, varscan2
- COL8A1 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV53743042; called by muse, mutect2, varscan2
- CYB5B | c.258T>A p.D86E | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV57175444; called by muse, varscan2
- EBPL | c.208G>A p.V70I | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.225); catalogued as rs1171601749, COSV54433899; called by muse, mutect2, varscan2
- EBPL | c.207C>A p.N69K | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.625); catalogued as COSV54433929; called by muse, mutect2, varscan2
- EFCAB5 | c.2488G>C p.D830H | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57937726; called by muse, mutect2, varscan2
- EPHA7 | c.2427G>T p.Q809H | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65191896; called by muse, mutect2, varscan2
- GNS | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 77/430 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs575544204, COSV50696685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPX3 | c.538C>A p.R180S | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.925); catalogued as COSV59303712, COSV59310372; called by muse, mutect2, varscan2
- GRAMD1A | c.353T>G p.I118S | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58769080; called by muse, mutect2, varscan2
- HERC5 | c.795T>G p.F265L | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV52045158; called by muse, mutect2, varscan2
- IL16 | c.3872C>T p.A1291V (on ENST00000302987 / NM_172217.5; = p.A590V on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as COSV57156098; called by muse, mutect2, varscan2
- INTS13 | c.2044A>T p.R682* | Nonsense Mutation (SNP) | VAF 140/327 reads (43%) | catalogued as COSV53905596; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs148006565; called by muse, mutect2, varscan2
- LARP1B | c.1418G>C p.R473P | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs142360155, COSV104390498, COSV52798417, COSV52803062; called by muse, mutect2, varscan2
- LMO4 | c.237-1G>C p.X79_splice | Splice Site (SNP) | VAF 22/78 reads (28%) | catalogued as COSV65170651; called by muse, mutect2, varscan2
- MMRN2 | c.2426G>C p.G809A | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.095); catalogued as COSV64401405; called by muse, mutect2, varscan2
- MTUS1 | c.701C>A p.T234K | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as COSV50592964; called by muse, mutect2, varscan2
- MUC16 | c.20204T>C p.I6735T | Missense Mutation (SNP) | VAF 99/368 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as COSV67494859; called by muse, mutect2, varscan2
- MUC2 | c.2852C>T p.T951M | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs575288673; called by muse, mutect2, varscan2
- NBAS | c.1967A>G p.E656G | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV55737965; called by muse, mutect2, varscan2
- OXSR1 | c.1574G>A p.S525N | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61260640; called by muse, mutect2, varscan2
- PARS2 | c.628T>C p.Y210H | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64883445; called by muse, mutect2, varscan2
- PDZD8 | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1054791907, COSV57828592; called by muse, mutect2
- PIGU | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as COSV54166662; called by muse, mutect2, varscan2
- PIK3R4 | c.576_578del p.R193del | In Frame Del (DEL) | VAF 28/102 reads (27%) | catalogued as rs1219441853; called by pindel, varscan2
- PLPPR4 | c.1160C>G p.T387R | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV64567753; called by muse, mutect2, varscan2
- POU6F2 | c.367A>T p.I123F | Missense Mutation (SNP) | VAF 51/212 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV68882733; called by muse, mutect2, varscan2
- PRAMEF4 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.161); catalogued as rs752857215, COSV52441461; called by muse, mutect2, varscan2
- RCCD1 | c.959A>C p.E320A | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV67793922; called by muse, mutect2, varscan2
- RHOT2 | c.382A>G p.M128V | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.236); catalogued as rs762371018, COSV53475384; called by muse, mutect2, varscan2
- SAYSD1 | c.522G>C p.E174D | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV57723613; called by muse, mutect2, varscan2
- SEC23A | c.1977T>G p.Y659* | Nonsense Mutation (SNP) | VAF 35/105 reads (33%) | catalogued as COSV56978950; called by muse, mutect2, varscan2
- SFXN4 | c.466A>C p.S156R | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57461091; called by muse, mutect2, varscan2
- SLC16A4 | c.507_510del p.D170Cfs*16 | Frame Shift Del (DEL) | VAF 37/151 reads (25%) | catalogued as rs745607177; called by mutect2, pindel, varscan2
- SLC22A9 | c.1293G>A p.M431I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV54170464; called by muse, mutect2
- SLC35G5 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55315340; called by muse, mutect2, varscan2
- TBC1D5 | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 32/86 reads (37%) | catalogued as COSV53771262; called by muse, mutect2, varscan2
- THAP10 | c.613C>A p.L205M | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.189); catalogued as COSV51437272; called by muse, mutect2, varscan2
- THBS3 | c.1451T>A p.L484H | Missense Mutation (SNP) | VAF 95/377 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.401); catalogued as COSV64250872; called by muse, mutect2, varscan2
- TIAM2 | c.2461G>A p.G821R | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); catalogued as rs760230451, COSV59704433; called by muse, mutect2, varscan2
- TLL2 | c.174C>T p.A58= | Splice Region (SNP) | VAF 19/72 reads (26%) | catalogued as rs745414954, COSV63574620, COSV63576014; called by muse, mutect2, varscan2
- TRPV4 | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs754848195, COSV55685833; ClinVar: uncertain significance; called by muse, mutect2
- TTC39C | c.1060G>A p.V354I (on ENST00000317571 / NM_001135993.2; = p.V293I on NM_153211.4) | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as rs1241212641, COSV58221260; called by muse, mutect2, varscan2
- TXN | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 48/299 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.021); catalogued as COSV65731325; called by muse, mutect2, varscan2
- UBA5 | c.334A>G p.N112D | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53906266; called by muse, varscan2
- UBE4B | c.456A>T p.E152D | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV53542583; called by muse, mutect2, varscan2
- USF3 | c.3474G>T p.R1158S | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.575); catalogued as COSV57077529; called by muse, mutect2, varscan2
- VAT1 | c.1127A>C p.E376A | Missense Mutation (SNP) | VAF 117/493 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV55896986; called by muse, mutect2, varscan2
- VHL | c.333_334insA p.Y112Ifs*20 | Frame Shift Ins (INS) | VAF 4/8 reads (50%) | catalogued as COSV56562542; called by mutect2, varscan2
- WDR11 | c.2999G>A p.C1000Y | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54793326; called by muse, mutect2, varscan2
- XPO7 | c.1261G>C p.V421L | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV53020511; called by muse, mutect2, varscan2
- ZC3H18 | c.2585C>T p.S862L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.725); catalogued as rs749335369, COSV56323475; called by muse, mutect2, varscan2
- ZNF76 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 83/363 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57592809; called by muse, mutect2, varscan2
- BAP1 | c.1004_1023del p.V335Efs*56 | Frame Shift Del (DEL) | VAF 39/139 reads (28%) | called by mutect2, pindel*, varscan2
- CYB5B | c.259_260del p.A87Qfs*11 | Frame Shift Del (DEL) | VAF 22/135 reads (16%) | called by muse*, mutect2, varscan2*
- DMPK | c.538_539insATTGATTG p.V180Dfs*2 | Nonsense Mutation (INS) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- FRMD5 | c.1581del p.D528Tfs*37 | Frame Shift Del (DEL) | VAF 12/95 reads (13%) | called by mutect2, pindel, varscan2
- INSM2 | c.1662del p.V555Cfs*58 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | called by mutect2, pindel, varscan2
- LDHC | c.705del p.Q236Kfs*9 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- MUC2 | c.3667C>A p.P1223T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RPGRIP1 | c.3273_3277del p.E1092Tfs*6 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- TBP | c.682_684del p.E228del | In Frame Del (DEL) | VAF 22/90 reads (24%) | called by pindel, varscan2
- TFDP2 | c.1067del p.P356Lfs*4 (on ENST00000489671 / NM_001178139.2; = p.P296Lfs*4 on NM_006286.5) | Frame Shift Del (DEL) | VAF 42/178 reads (24%) | called by mutect2, pindel, varscan2
- VCPIP1 | c.3425_3430del p.E1142_V1143del | In Frame Del (DEL) | VAF 62/268 reads (23%) | called by mutect2, pindel, varscan2
- AXIN2 | c.2106C>A p.R702= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV61061208; called by muse, mutect2
- CAPN6 | c.1311C>T p.H437= | Silent (SNP) | VAF 44/187 reads (24%) | catalogued as COSV60697269; called by muse, mutect2, varscan2
- DCTPP1 | c.307C>T p.L103= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV60000918; called by muse, mutect2, varscan2
- DENND3 | c.1765C>A p.R589= | Silent (SNP) | VAF 46/197 reads (23%) | catalogued as COSV52801052, COSV52807046; called by muse, mutect2, varscan2
- FBXL18 | c.600C>T p.Y200= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1479733854, COSV66668697; called by muse, mutect2
- FCGBP | c.8382C>T p.Y2794= | Silent (SNP) | VAF 22/89 reads (25%) | called by muse, mutect2, varscan2
- FETUB | c.675A>T p.S225= | Silent (SNP) | VAF 82/299 reads (27%) | catalogued as COSV54007221; called by muse, mutect2, varscan2
- GRID1 | c.2074C>A p.R692= | Silent (SNP) | VAF 119/498 reads (24%) | catalogued as COSV60053966; called by muse, mutect2, varscan2
- LAMC2 | c.1686G>A p.L562= | Silent (SNP) | VAF 52/208 reads (25%) | catalogued as COSV51454833, COSV51459830; called by muse, varscan2
- LLGL2 | c.2559T>C p.S853= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99390182; called by muse, mutect2, varscan2
- MUC16 | c.20205C>A p.I6735= | Silent (SNP) | VAF 96/368 reads (26%) | catalogued as rs1466781042, COSV67445615, COSV67494852; called by muse, mutect2, varscan2
- N4BP2 | c.2796C>T p.G932= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs754357575, COSV54707028; called by muse, mutect2, varscan2
- NR2C2AP | c.243G>A p.Q81= | Silent (SNP) | VAF 83/311 reads (27%) | catalogued as COSV57395125; called by muse, mutect2, varscan2
- OBI1 | c.1185T>C p.L395= | Silent (SNP) | VAF 10/254 reads (4%) | catalogued as COSV56147506; called by muse, mutect2
- PDE4A | c.909C>T p.P303= (on ENST00000380702 / NM_001111307.2; = p.P64= on NM_006202.3) | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV53362883; called by muse, mutect2, varscan2
- PLEKHA4 | c.495T>G p.P165= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV54366342; called by muse, mutect2, varscan2
- TNPO2 | c.828G>A p.E276= | Silent (SNP) | VAF 37/177 reads (21%) | catalogued as COSV63510215; called by muse, mutect2, varscan2
- UBR5 | c.1128T>C p.A376= | Silent (SNP) | VAF 70/371 reads (19%) | catalogued as COSV55300539; called by muse, mutect2, varscan2
- UQCRB | c.198A>T p.A66= | Silent (SNP) | VAF 61/208 reads (29%) | catalogued as COSV54630857; called by muse, mutect2, varscan2
- ZNF831 | c.222C>T p.R74= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs763329350, COSV64040907, COSV64042592; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505932 C>A | 5'Flank (SNP) | VAF 46/141 reads (33%) | called by muse, mutect2, varscan2
- BAGE2 | n.193C>T | RNA (SNP) | VAF 16/152 reads (11%) | catalogued as rs750289446; called by muse, mutect2, varscan2
- DELEC1 | n.628A>G | RNA (SNP) | VAF 8/84 reads (10%) | catalogued as COSV64986700; called by muse, mutect2
- DLG2 | c.205-65747C>A | Intron (SNP) | VAF 53/192 reads (28%) | catalogued as COSV99715320, COSV99718016; called by mutect2, varscan2
